Somatic mutation profile of tumor specimen 1105263 (aliquot 7316UP-426-1105263) from CPTAC case C298152, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen 1105263: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab8bfd2b-7df2-487c-b15a-da768d46782d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105208 (Blood Derived Normal), aliquot 7316UP-426-1105208; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50a8b1a4-c80d-49ad-9118-74ebf7630473

The open-access MAF lists 41 somatic variants for this specimen: 26 protein-altering or splice-affecting, 11 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 11, Nonsense Mutation 1, Intron 1, 5'UTR 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.521A>G p.Y174C | Missense Mutation (SNP) | VAF 88/123 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs864622341, COSV64290156; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- USH2A | c.10450C>T p.R3484* | Nonsense Mutation (SNP) | VAF 54/110 reads (49%) | catalogued as rs111033379, CM080610, COSV56427899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs779902900, COSV60922721; called by muse, mutect2, varscan2
- CPAMD8 | c.1474G>A p.G492S (on ENST00000651564; = p.G445S on NM_015692.5) | Missense Mutation (SNP) | VAF 98/247 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as rs574048580; called by muse, mutect2, varscan2
- CPZ | c.1862C>T p.A621V (on ENST00000360986 / NM_001014447.3; = p.A610V on NM_003652.3) | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs201930593, COSV100249106; called by muse, mutect2, varscan2
- DDX43 | c.105G>T p.L35F | Missense Mutation (SNP) | VAF 68/412 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.086); catalogued as COSV100946485, COSV64836729; called by muse, mutect2, varscan2
- JPH1 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 98/228 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs748452859, COSV60608792; called by muse, mutect2, varscan2
- MTHFR | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775829502, COSV100928224; called by muse, mutect2
- MUC5B | c.1106C>T p.T369M | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs554624154; called by muse, mutect2, varscan2
- NPNT | c.1225G>A p.D409N | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs778565408, COSV59753816; called by muse, mutect2, varscan2
- OBSCN | c.13361C>T p.T4454M | Missense Mutation (SNP) | VAF 77/194 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs758896862, COSV52750133, COSV52751888; called by muse, mutect2, varscan2
- PCLO | c.8125C>A p.H2709N | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as COSV61653611; called by muse, mutect2, varscan2
- PLCG1 | c.2120G>A p.R707Q | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54814695; called by muse, mutect2, varscan2
- RELB | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 109/271 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.289); catalogued as rs571786771, COSV55513078; called by muse, mutect2, varscan2
- RGS9 | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 155/368 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs913010766, COSV52225932; called by muse, mutect2, varscan2
- SIPA1L3 | c.1345G>A p.V449M | Missense Mutation (SNP) | VAF 116/251 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs370319919; called by muse, mutect2, varscan2
- TRPV6 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs775866936; called by muse, mutect2, varscan2
- WDR88 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.32); catalogued as rs201611292; called by muse, mutect2, varscan2
- AKAP9 | c.5905C>A p.Q1969K (on ENST00000359028; = p.Q1937K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/303 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- BTN3A3 | c.744G>T p.W248C | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EML3 | c.1074C>A p.F358L | Missense Mutation (SNP) | VAF 77/258 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR52B4 | c.769G>C p.G257R | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- PABPN1 | c.604A>G p.T202A | Missense Mutation (SNP) | VAF 96/394 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHGB5 | c.397T>A p.F133I | Missense Mutation (SNP) | VAF 82/252 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRAM1 | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRRAP | c.2623G>A p.A875T | Missense Mutation (SNP) | VAF 114/305 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ADIPOQ | c.624C>T p.G208= | Silent (SNP) | VAF 81/158 reads (51%) | catalogued as rs200876636; called by muse, mutect2, varscan2
- APBB1 | c.30G>A p.S10= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs777578946; called by muse, mutect2
- CNTNAP2 | c.2037C>T p.A679= | Silent (SNP) | VAF 157/476 reads (33%) | catalogued as rs539741829, COSV62276109; called by muse, mutect2, varscan2
- CPNE4 | c.93G>A p.A31= | Silent (SNP) | VAF 60/194 reads (31%) | catalogued as rs368853915, COSV70193650; called by muse, mutect2, varscan2
- FAM83H | c.1992G>A p.K664= | Silent (SNP) | VAF 133/339 reads (39%) | called by muse, mutect2, varscan2
- FTCD | c.1479C>T p.G493= | Silent (SNP) | VAF 199/572 reads (35%) | catalogued as rs576503541, COSV52430942; called by muse, mutect2, varscan2
- GABRD | c.153C>T p.Y51= | Silent (SNP) | VAF 60/144 reads (42%) | catalogued as rs148496176; called by muse, mutect2, varscan2
- RAB6C | c.606C>T p.S202= | Silent (SNP) | VAF 95/275 reads (35%) | catalogued as COSV101308492; called by muse, mutect2, varscan2
- SF3B3 | c.1848C>A p.I616= | Silent (SNP) | VAF 56/167 reads (34%) | called by muse, mutect2, varscan2
- TSBP1 | c.495C>T p.H165= (on ENST00000617061; = p.P175S on NM_006781.5) | Silent (SNP) | VAF 62/199 reads (31%) | called by muse, mutect2, varscan2
- ZNF461 | c.1368C>T p.L456= | Silent (SNP) | VAF 43/241 reads (18%) | catalogued as COSV64452884, COSV64455033; called by muse, mutect2, varscan2
- AC058822.1 | c.1018-288066G>C | Intron (SNP) | VAF 48/119 reads (40%) | called by muse, mutect2, varscan2
- GNL1 | c.-940C>T | 5'UTR (SNP) | VAF 163/381 reads (43%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159896 G>A | 5'Flank (SNP) | VAF 38/82 reads (46%) | catalogued as rs1413811503; called by muse, mutect2, varscan2
- SNORD116-6 | n.84G>A | RNA (SNP) | VAF 62/183 reads (34%) | catalogued as rs756590960; called by muse, mutect2, varscan2
